Somatic mutation profile of tumor specimen RC-B65D-TBP1-A (aliquot RC-B65D-TBP1-A-1-0-D-A93N-47) from RC case RC-B65D, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: female; Vital status: Dead; Primary diagnosis: Prolymphocytic leukemia, T-cell type; Tissue or organ of origin: Bone marrow; Age at diagnosis: 69.0 years (25,186 days).
Specimen RC-B65D-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f55797d5-afa5-4160-a25a-beb28268e9da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen RC-B65D-NB1-A (Granulocytes; tissue type Normal), aliquot RC-B65D-NB1-A-1-0-D-A93N-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc2b2df7-9e5b-4dd4-b653-f12ea321347e

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 2, In Frame Ins 1, Frame Shift Ins 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHRR | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as rs1226713109, COSV57096292; called by muse, mutect2
- DDX3X | c.106C>G p.R36G (on ENST00000399959; = p.R37G on NM_001356.5) | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.524); catalogued as COSV67864090; called by muse, mutect2, varscan2
- HHIPL2 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.056); catalogued as rs753929029, COSV58564406; called by muse, mutect2, varscan2
- INSYN2A | c.1346C>T p.S449L | Missense Mutation (SNP) | VAF 58/198 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs753834736; called by muse, varscan2
- LATS1 | c.3157G>A p.E1053K | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs1165460532; called by muse, mutect2, varscan2
- MAGEA4 | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 101/251 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs755062941, COSV52340702; called by muse, mutect2, varscan2
- TRAPPC12 | c.208G>A p.V70I | Missense Mutation (SNP) | VAF 62/232 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as rs1477712835, COSV104408764; called by muse, mutect2, varscan2
- EMC7 | c.229T>G p.F77V | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- GDF1 | c.964G>C p.A322P | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); called by muse, varscan2
- GJA9 | c.877_878insGCACAC p.T292_H293insRT | In Frame Ins (INS) | VAF 44/130 reads (34%) | called by pindel, varscan2
- GJA9 | c.871dup p.Q291Pfs*9 | Frame Shift Ins (INS) | VAF 57/151 reads (38%) | called by muse*, mutect2, varscan2*
- KRTAP26-1 | c.603C>G p.S201R | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- RPL34 | c.16A>C p.T6P | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2
- RYR1 | c.3620T>G p.V1207G | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.45); called by muse, mutect2
- ZNF302 | c.584T>A p.L195* (on ENST00000627982; = p.L116* on NM_018443.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 38/140 reads (27%) | called by muse, mutect2, varscan2
- IKBKG | c.486T>C p.A162= | Silent (SNP) | VAF 31/294 reads (11%) | called by muse, mutect2, varscan2
- KRT85 | c.726G>A p.L242= | Silent (SNP) | VAF 42/106 reads (40%) | called by muse, varscan2
- PLCZ1 | c.570-2720T>A | Intron (SNP) | VAF 17/154 reads (11%) | called by muse, mutect2, varscan2
